Somatic mutation profile of tumor specimen MP2PRT-PATYWT-TMP1-A (aliquot MP2PRT-PATYWT-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATYWT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,827 days).
Specimen MP2PRT-PATYWT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3585da4-987a-4433-b362-f1322f34dbff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYWT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYWT-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a60e87c-d3d1-4d40-8a59-70ebc7af266d

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A3 | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565278340, COSV53419927; called by muse, mutect2
- MGA | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 38/275 reads (14%) | catalogued as COSV54949906; called by muse, mutect2, varscan2
- MMP21 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 193/539 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs1348079859; called by muse, mutect2, varscan2
- RFX1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1262297690; called by muse, mutect2, varscan2
- AC004593.2 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BMX | c.588C>T p.N196= | Silent (SNP) | VAF 150/417 reads (36%) | catalogued as rs774649678; called by muse, mutect2, varscan2
- PPP1R10 | c.2796G>A p.P932= | Silent (SNP) | VAF 169/442 reads (38%) | catalogued as rs150463278; called by muse, mutect2, varscan2
- SLITRK5 | c.876C>T p.Y292= | Silent (SNP) | VAF 42/357 reads (12%) | catalogued as rs762791677, COSV61527454; called by muse, mutect2, varscan2
- SORCS2 | c.1857G>A p.T619= | Silent (SNP) | VAF 97/249 reads (39%) | catalogued as rs374246564; called by muse, mutect2, varscan2
- MAP4 | c.2000-13730C>G | Intron (SNP) | VAF 120/283 reads (42%) | called by muse, mutect2, varscan2
